MMRF case MMRF_1932 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0b01a9c3-98f9-4ab8-a401-a3b1f087dd06

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.0 years (24,102 days); ISS stage: II; Days to last known disease status: 1,072 days (2.9 years); Days to last follow up: 1,072 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 325 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,072.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 2): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Beta 2 Microglobulin 5.4 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.6 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.7 mmol/L; Albumin 27 g/L; Total Protein 9.7 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 0.7 mg/dL.
- Day 80 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.1 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 1.31 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 164 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 8.65 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.84 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 9.29 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.63 mmol/L; Albumin 47 g/L; Total Protein 6.5 g/dL; Glucose 6.82 mmol/L.
- Day 255 (ECOG 1): Hemoglobin 7.75 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 353 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 0.7 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.83 µg/mL; Hemoglobin 8.12 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.94 mmol/L.
- Day 437 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 528 (ECOG 1): Immunoglobulin G 7.25 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.92 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.13 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 619 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.67 g/L; Beta 2 Microglobulin 5.91 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 10.3 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 243 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 7.92 mmol/L.
- Day 717 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 10.2 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 3.8 mmol/L.
- Day 801 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.67 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 10.7 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.33 mmol/L.
- Day 892: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 10.8 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 977 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.73 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 10.5 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.03 mmol/L; Albumin 34 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -6: Weight: 67 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1932_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1932_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
